Somatic mutation profile of tumor specimen MBCProject_0075_T1_WES (aliquot MBCProject_0075_T1_WES_1) from CMI case MBCProject_0075, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 30.9 years (11,293 days).
Specimen MBCProject_0075_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af0fc248-5b66-4bdf-ba18-8bfc1b2929eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0075_SALIVA (Saliva), aliquot MBCProject_0075_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e85269f-a523-4111-bf7f-5388f243b70b

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, RNA 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 24/379 reads (6%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV52517971, COSV52518546; called by muse, mutect2
- TP53 | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 18/160 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AATK | c.1448C>T p.A483V (on ENST00000326724 / NM_001080395.3; = p.A380V on NM_004920.2) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV58686895; called by muse, mutect2, varscan2
- CACNB2 | c.1054G>C p.A352P (on ENST00000324631 / NM_201596.3; = p.A297P on NM_000724.4) | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs769771426; called by muse, mutect2, varscan2
- CYP46A1 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV99952845; called by muse, mutect2
- ELOA2 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV99797388; called by muse, mutect2
- FAM120B | c.1850G>T p.S617I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs780201901; called by muse, mutect2, varscan2
- GFRAL | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV61231152; called by muse, mutect2
- HEATR1 | c.3247G>C p.D1083H | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs1195526194; called by muse, mutect2
- LARP4B | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1007810809; called by muse, mutect2
- LDHC | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs760395380, COSV55004394; called by muse, mutect2, varscan2
- MAGEE1 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63912077; called by muse, mutect2
- OR6J1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs1349115054; called by muse, mutect2, varscan2
- RPS6KA2 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs758929555, COSV55823381; called by muse, mutect2, varscan2
- TIMM23 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.881); catalogued as rs782349833; called by muse, mutect2
- TRIO | c.4425G>T p.G1475= | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as COSV60077527; called by muse, varscan2
- COL9A1 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2
- DPYS | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- KCP | c.3072G>C p.L1024F (on ENST00000620378; = p.L1084F on NM_001366122.1) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LCOR | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2
- LGALS13 | c.130A>T p.M44L | Missense Mutation (SNP) | VAF 108/558 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC16 | c.4990A>C p.M1664L | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7B | c.4084G>C p.E1362Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- NFATC1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OAZ3 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, varscan2
- PRSS12 | c.2346A>C p.Q782H | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- INTU | c.33G>A p.P11= | Silent (SNP) | VAF 8/171 reads (5%) | catalogued as COSV99078853; called by muse, mutect2
- MRPS22 | c.519C>T p.V173= (on ENST00000310776 / NM_001363893.1; = p.V174= on NM_020191.4) | Silent (SNP) | VAF 29/338 reads (9%) | called by muse, mutect2
- PRAM1 | c.1722G>A p.R574= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs746661892, COSV99725131; called by muse, mutect2, varscan2
- SLFN12 | c.843G>A p.K281= | Silent (SNP) | VAF 1054/1320 reads (80%) | catalogued as COSV59226483; called by muse, mutect2, varscan2
- SLFN12 | c.108G>A p.L36= | Silent (SNP) | VAF 449/555 reads (81%) | catalogued as COSV59225248; called by muse, mutect2, varscan2
- TMEM144 | c.291C>T p.I97= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- ZXDC | c.558C>T p.F186= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, varscan2
- AKAP4 | c.-35C>G | 5'UTR (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- SPCS2P4 | n.528C>A | RNA (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
